Surgical pathology report (de-identified scan), TCGA case TCGA-4V-A9QT, project TCGA-THYM (Thymoma), tissue source site Hospital Louis Pradel, specimen TCGA-4V-A9QT-01A (Primary Tumor).

Nature of sampling : Thymectomy

Macroscopic examination :

1 - Thymectomy :

The piece weighs 189 g thymectomy fresh and addressed oriented . it measures 12 cm x 14 cm x 5 cm. The limits of resection are marked in ink green machine. In the presence of a nodule 8 cm x 7 cm x 5 cm , located on the lower horn section right , although limited by an individual capsule. Tumor parenchyma is marked by rearrangements necrotic and hemorrhagic .

Histopathological examination :

The general architecture is lobulated tumor, separated by septa. The tumor consists essentially of lymphocytes to small type lymphocytes. The presence of numerous macrophages gives the tumor a starry sky aspect. Differentiation medullary zones are numerous.

Epithelial tumor cells are small virtually devoid of atypia characterized by a pale nucleus with a small nucleolus. They are poorly visible, scattered and isolated within the lymphocyte quota. Perivascular spaces are rare.

The tumor appears well limited by the often thin capsule.

The limits of surgical resection marked in ink green are not invaded.

The samples taken at the normal thymus adjacent to the tumor (F and G) are characterized by thymic involution parenchyma partially fat . this fabric adipose tumor perished contains several nodules B1 thymoma .

Immunohistochemical study :

- Epithelial Cells :
positive and diffuse CK19 , CK18 and CK7 low of
absence of labeling with the CK20 , CD 5 and CD20
- Lymphocytes: T CD1A immature , CD5 , CD99

Conclusion :

Thymoma subtype B1, measuring 8 cm by 7 cm .

Tumor with minimal infiltration.

Complete resection .

Modified Masaoka stage II classification.

WHO classification T2N0M0

TCGA-3
Thymoma, type B1, malignant
8588/13
Site: Thymus C37.9
9/4/2/14

electronic signature

Source: NCI Genomic Data Commons file 091ff9e0-f6ee-4fb3-8c28-e1be838fab2a (TCGA-4V-A9QT.6DE2C3B0-230E-45D5-B78B-9D3C50F17A0C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).